Somatic mutation profile of tumor specimen ALCH-AENC-TTP1-A (aliquot ALCH-AENC-TTP1-A-2-0-D-A667-36) from ALCHEMIST case ALCH-AENC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Large cell carcinoma, NOS; Age at diagnosis: 66.2 years (24,173 days).
Specimen ALCH-AENC-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85097da4-bb79-47a5-94f7-38cb75456b1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AENC-NB1-A (Blood Derived Normal), aliquot ALCH-AENC-NB1-A-1-0-D-A667-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f0a8cec-723c-4bd7-a95f-624b749b8d8e

The open-access MAF lists 561 somatic variants for this specimen: 393 protein-altering or splice-affecting, 102 silent, 66 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 337, Silent 102, Intron 39, Nonsense Mutation 17, Frame Shift Del 16, Splice Site 14, RNA 11, 5'UTR 8, Frame Shift Ins 4, 3'UTR 4, 5'Flank 3, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1510C>T p.Q504* | Nonsense Mutation (SNP) | VAF 85/126 reads (67%) | catalogued as rs886043247, CM030506, COSV57295964, COSV99927064; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.560-1G>T p.X187_splice | Splice Site (SNP) | VAF 97/140 reads (69%) | hotspot (GDC flag); catalogued as CD043957, CS011574, CS083991, COSV52662318, COSV52676510, COSV52683087, COSV52690533; called by muse, mutect2, varscan2
- ABCA13 | c.762C>G p.T254= | Splice Region (SNP) | VAF 62/155 reads (40%) | catalogued as COSV70047850; called by muse, mutect2, varscan2
- ACACB | c.3610T>G p.S1204A | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as rs1356312009; called by muse, mutect2, varscan2
- ADAMTS20 | c.1958G>T p.R653L | Missense Mutation (SNP) | VAF 47/204 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101239406; called by muse, mutect2, varscan2
- ADCY5 | c.502C>A p.R168S | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.02); catalogued as rs1334092186; called by muse, mutect2, varscan2
- ADD3 | c.754C>G p.Q252E | Missense Mutation (SNP) | VAF 91/132 reads (69%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.81); catalogued as COSV53324513; called by muse, mutect2, varscan2
- AK9 | c.5086G>A p.A1696T | Missense Mutation (SNP) | VAF 68/176 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV69853366, COSV69853872; called by muse, mutect2, varscan2
- ALX1 | c.475G>T p.V159L | Missense Mutation (SNP) | VAF 73/171 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV57491034; called by muse, mutect2, varscan2
- AMOTL1 | c.2035G>T p.A679S | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV58567849; called by muse, mutect2, varscan2
- ANK2 | c.8105A>G p.N2702S | Missense Mutation (SNP) | VAF 45/266 reads (17%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0.007); catalogued as rs748404965; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP15 | c.738C>A p.S246R | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV54497846; called by mutect2, varscan2
- ARHGAP28 | c.790C>T p.P264S (on ENST00000383472 / NM_001366230.1; = p.P105S on NM_001010000.3) | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs191955313; called by muse, mutect2, varscan2
- ASCC3 | c.3745G>T p.E1249* | Nonsense Mutation (SNP) | VAF 1545/1796 reads (86%) | catalogued as COSV100226391; called by muse, mutect2, varscan2
- ATM | c.9007A>C p.N3003H | Missense Mutation (SNP) | VAF 41/356 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53744107, COSV53761060; called by muse, mutect2, varscan2
- AZIN2 | c.380A>T p.H127L | Missense Mutation (SNP) | VAF 19/214 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1036712762; called by muse, mutect2, varscan2
- BMPR2 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 118/264 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV65810927; called by muse, varscan2
- BSND | c.416C>A p.P139Q | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV64870710; called by muse, mutect2, varscan2
- C12orf40 | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 64/227 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100210165; called by muse, mutect2, varscan2
- C6orf201 | c.383-2A>G p.X128_splice | Splice Site (SNP) | VAF 128/353 reads (36%) | catalogued as COSV60986212; called by muse, mutect2, varscan2
- CLSTN2 | c.2575C>A p.H859N | Missense Mutation (SNP) | VAF 75/193 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV71721550; called by muse, mutect2, varscan2
- COL24A1 | c.3710G>A p.G1237D | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1159499147; called by muse, mutect2, varscan2
- CXorf21 | c.220C>A p.Q74K | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.09); catalogued as COSV66762357, COSV66762998; called by muse, mutect2, varscan2
- DCBLD2 | c.2227C>T p.P743S | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1304387834; called by muse, mutect2, varscan2
- DLX3 | c.208A>G p.N70D | Missense Mutation (SNP) | VAF 81/182 reads (45%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.777); catalogued as COSV101460515; called by muse, mutect2, varscan2
- DNAH7 | c.10217G>T p.G3406V | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs906169840, COSV56759131; called by muse, mutect2, varscan2
- DPPA4 | c.134C>A p.S45* | Nonsense Mutation (SNP) | VAF 104/220 reads (47%) | catalogued as COSV59509371; called by muse, mutect2, varscan2
- ERRFI1 | c.301G>C p.E101Q | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.307); catalogued as COSV101088117; called by muse, mutect2
- ETV3L | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 41/71 reads (58%) | catalogued as COSV71901024; called by muse, mutect2, varscan2
- EVC2 | c.2359C>T p.R787W | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs776830520, COSV100186115; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EVI5 | c.2432G>T p.*811Lext*4 | Nonstop Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100945469; called by muse, varscan2
- FAM71B | c.871C>G p.P291A | Missense Mutation (SNP) | VAF 42/70 reads (60%) | SIFT tolerated (0.17); PolyPhen benign (0.084); catalogued as COSV100262204; called by muse, mutect2, varscan2
- FAT2 | c.4106G>T p.G1369V | Missense Mutation (SNP) | VAF 68/105 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759936860, COSV99944595; called by muse, mutect2, varscan2
- FH | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as rs981562354; ClinVar: uncertain significance; called by muse, varscan2
- FHL1 | c.908T>A p.V303E (on ENST00000651089 / NM_001369326.1; = p.S236R on NM_001449.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/189 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV61783207; called by muse, mutect2, varscan2
- FLT4 | c.2571del p.K858Rfs*21 | Frame Shift Del (DEL) | VAF 38/87 reads (44%) | catalogued as COSV56115975; called by mutect2, pindel, varscan2
- FNDC1 | c.3518A>G p.Q1173R | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as rs375160477; called by muse, mutect2, varscan2
- FOXP3 | c.1241G>C p.R414P | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66051211; called by muse, mutect2, varscan2
- GABPB2 | c.1037A>T p.E346V | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as COSV100927192; called by muse, mutect2, varscan2
- GRIK3 | c.1033G>T p.V345L | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as COSV100902388; called by muse, mutect2, varscan2
- GRIK4 | c.898G>A p.G300R | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); catalogued as COSV101483516; called by muse, mutect2
- GTPBP2 | c.61G>A p.V21M | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs768182541; called by muse, mutect2, varscan2
- HOMER2 | c.760G>A p.E254K (on ENST00000304231 / NM_199330.3; = p.E243K on NM_004839.4) | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs754047402; called by muse, mutect2, varscan2
- HSPB7 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as rs765611158; called by muse, mutect2, varscan2
- IGF2R | c.767G>T p.R256L | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.148); catalogued as rs371916370; called by muse, mutect2, varscan2
- IGSF22 | c.2215C>G p.R739G (on ENST00000319338; = p.R840G on NM_173588.4) | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.981); catalogued as COSV60038196; called by muse, mutect2, varscan2
- ITGA8 | c.1970C>A p.P657Q | Missense Mutation (SNP) | VAF 66/98 reads (67%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.693); catalogued as COSV100959555; called by muse, mutect2, varscan2
- ITM2A | c.209G>T p.G70V | Missense Mutation (SNP) | VAF 102/235 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1266440922; called by muse, mutect2, varscan2
- JHY | c.1238C>T p.S413L | Missense Mutation (SNP) | VAF 54/280 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs139995595, COSV57078751; called by muse, mutect2, varscan2
- KANSL2 | c.341C>T p.T114I | Missense Mutation (SNP) | VAF 61/146 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as rs775015748; called by muse, mutect2, varscan2
- KDR | c.877A>G p.T293A | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); catalogued as rs548382655; called by muse, mutect2, varscan2
- KHDRBS2 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 29/255 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as rs201333575; called by muse, mutect2, varscan2
- KIAA1841 | c.1867A>G p.M623V | Missense Mutation (SNP) | VAF 29/235 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1337071516; called by muse, mutect2, varscan2
- LDB2 | c.259del p.R87Vfs*11 | Frame Shift Del (DEL) | VAF 23/110 reads (21%) | catalogued as COSV100453449, COSV100454251; called by mutect2, pindel, varscan2
- LFNG | c.1052C>T p.S351L (on ENST00000222725 / NM_001040167.2; = p.S222L on NM_002304.2) | Missense Mutation (SNP) | VAF 73/169 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs763866787; called by muse, mutect2, varscan2
- LGI4 | c.538G>A p.V180M | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1184063861; called by muse, mutect2, varscan2
- LILRA6 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 114/228 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV54428700; called by muse, mutect2, varscan2
- LRRC7 | c.422-1G>A p.X141_splice (on ENST00000651989 / NM_001370785.2; = p.X108_splice on NM_001330635.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 122/232 reads (53%) | catalogued as COSV99224582; called by muse, mutect2, varscan2
- MAGEE2 | c.1324C>A p.R442S | Missense Mutation (SNP) | VAF 71/193 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.045); catalogued as rs781070212, COSV100973158; called by muse, mutect2, varscan2
- MAP2 | c.4150G>T p.D1384Y | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1266392795; called by muse, mutect2, varscan2
- MCOLN2 | c.604C>A p.P202T | Missense Mutation (SNP) | VAF 118/219 reads (54%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV99393560; called by muse, mutect2, varscan2
- MORC1 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as COSV99226655; called by muse, mutect2, varscan2
- MTRNR2L5 | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 28/38 reads (74%) | PolyPhen benign (0); catalogued as rs766474179; called by muse, mutect2, varscan2
- MYH13 | c.5374C>A p.Q1792K | Missense Mutation (SNP) | VAF 62/115 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.388); catalogued as COSV99352856; called by muse, mutect2, varscan2
- NEXMIF | c.3694A>C p.I1232L | Missense Mutation (SNP) | VAF 55/184 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99281031; called by muse, mutect2, varscan2
- NRDC | c.1658C>T p.A553V | Missense Mutation (SNP) | VAF 60/91 reads (66%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as rs768282290; called by muse, mutect2, varscan2
- NTN4 | c.413G>A p.R138K | Missense Mutation (SNP) | VAF 103/289 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760664968; called by muse, mutect2, varscan2
- NTNG2 | c.1139C>A p.T380K | Missense Mutation (SNP) | VAF 77/103 reads (75%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV62366326; called by muse, mutect2, varscan2
- NYX | c.946G>A p.V316M | Missense Mutation (SNP) | VAF 72/232 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV61181802; called by muse, mutect2, varscan2
- OPRK1 | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.927); catalogued as rs186551684; called by muse, mutect2, varscan2
- OR4B1 | c.258G>T p.K86N | Missense Mutation (SNP) | VAF 102/206 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as COSV100535654; called by muse, mutect2, varscan2
- OR4P4 | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100111668; called by muse, mutect2, varscan2
- OR51G2 | c.609C>G p.Y203* | Nonsense Mutation (SNP) | VAF 25/199 reads (13%) | catalogued as COSV58993216; called by muse, mutect2, varscan2
- OR51V1 | c.74A>C p.Q25P | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.222); catalogued as COSV58315096; called by muse, varscan2
- OR5T1 | c.843C>A p.D281E | Missense Mutation (SNP) | VAF 44/257 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as rs925184002; called by muse, mutect2, varscan2
- OR8B12 | c.443A>G p.Y148C | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as rs761289895; called by muse, mutect2, varscan2
- OTOG | c.7075G>C p.V2359L | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as rs1189133443; called by muse, mutect2, varscan2
- PAG1 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 16/221 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs775054099, COSV55058178; called by muse, mutect2
- PCARE | c.1310G>T p.S437I | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.103); catalogued as rs779690773; called by muse, mutect2, varscan2
- PDE3A | c.1571C>T p.S524L | Missense Mutation (SNP) | VAF 21/203 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as rs773689273, COSV62969394; called by muse, mutect2
- PDZD4 | c.67G>T p.G23W | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51249634; called by muse, mutect2
- PJA1 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs779128771; called by muse, mutect2, varscan2
- PLEKHN1 | c.1945C>A p.Q649K (on ENST00000379409; = p.Q597K on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.121); catalogued as rs866006704; called by muse, mutect2, varscan2
- PPP4R2 | c.292C>A p.P98T | Missense Mutation (SNP) | VAF 110/179 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55594386; called by muse, mutect2, varscan2
- PRKD1 | c.1061G>T p.S354I | Missense Mutation (SNP) | VAF 158/482 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs1425147156; called by muse, mutect2, varscan2
- PXDN | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.668); catalogued as rs773723398, COSV53225592, COSV53247591; called by muse, mutect2, varscan2
- RABGAP1L | c.622G>A p.G208R | Missense Mutation (SNP) | VAF 34/315 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs758204407; called by muse, mutect2, varscan2
- RC3H2 | c.1421G>T p.G474V | Missense Mutation (SNP) | VAF 116/190 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as COSV61798216; called by muse, mutect2, varscan2
- RIT2 | c.559A>G p.M187V | Missense Mutation (SNP) | VAF 233/536 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1406264401; called by muse, mutect2, varscan2
- RNF175 | c.283T>C p.Y95H | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.894); catalogued as rs761835001, COSV56843138; called by muse, mutect2, varscan2
- SCIN | c.769G>A p.A257T (on ENST00000297029 / NM_001112706.3; = p.A10T on NM_033128.3) | Missense Mutation (SNP) | VAF 109/249 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs763469468; called by muse, mutect2, varscan2
- SDK1 | c.4139C>G p.P1380R | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749738707; called by muse, mutect2, varscan2
- SEL1L2 | c.59C>T p.T20I | Missense Mutation (SNP) | VAF 83/320 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.023); catalogued as COSV99533494; called by muse, mutect2, varscan2
- SLC8A3 | c.1889C>T p.A630V (on ENST00000381269 / NM_183002.3; = p.A631V on NM_033262.4) | Missense Mutation (SNP) | VAF 66/250 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as rs774149200, COSV53688951, COSV53692198; called by muse, mutect2, varscan2
- SLITRK2 | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as rs782518844, COSV59429934; called by muse, mutect2, varscan2
- SMG1 | c.2384T>C p.L795S | Missense Mutation (SNP) | VAF 78/161 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV67173918; called by muse, mutect2, varscan2
- SMG1 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 66/301 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs765587087, COSV67169826; called by muse, mutect2, varscan2
- SPHKAP | c.3225del p.W1075* | Frame Shift Del (DEL) | VAF 32/88 reads (36%) | catalogued as COSV60879794; called by mutect2, pindel, varscan2
- SPRED2 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 32/74 reads (43%) | catalogued as COSV62695227; called by muse, mutect2, varscan2
- SSUH2 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.07); catalogued as rs767428753, COSV58031755; called by muse, mutect2, varscan2
- STS | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 18/442 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM034300, COSV99481269; called by muse, mutect2
- SYNE1 | c.21657-1G>T p.X7219_splice (on ENST00000367255 / NM_182961.4; = p.X7148_splice on NM_033071.3) | Splice Site (SNP) | VAF 52/205 reads (25%) | catalogued as COSV54955112; called by muse, mutect2, varscan2
- SYT13 | c.410-1G>T p.X137_splice | Splice Site (SNP) | VAF 12/50 reads (24%) | catalogued as COSV50073894; called by muse, mutect2, varscan2
- TCEAL2 | c.610C>A p.P204T | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61197766; called by muse, mutect2, varscan2
- TENM2 | c.5633G>A p.R1878H (on ENST00000518659 / NM_001122679.2; = p.R1639H on NM_001080428.3) | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs754293472; called by muse, mutect2, varscan2
- TFDP3 | c.1109C>A p.S370Y | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as COSV59538519; called by muse, mutect2
- TIAM1 | c.1973C>T p.S658L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs1462610021, COSV54555018; called by muse, mutect2, varscan2
- TMEM132C | c.2471G>A p.R824H | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs367776856; called by muse, mutect2
- TMEM19 | c.881G>T p.S294I | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.091); catalogued as COSV56999893; called by muse, mutect2, varscan2
- TRIT1 | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 2360/2580 reads (91%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs866540220; called by muse, mutect2, varscan2
- TTN | c.62911G>A p.D20971N (on ENST00000591111; = p.D13547N on NM_003319.4) | Missense Mutation (SNP) | VAF 65/235 reads (28%) | PolyPhen probably damaging (0.998); catalogued as rs757888367, COSV60313118; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- UBE2J2 | c.619G>T p.G207W | Missense Mutation (SNP) | VAF 54/97 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs928340026, COSV59572156; called by muse, mutect2, varscan2
- UGT1A9 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 107/256 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV100693099; called by muse, mutect2, varscan2
- UNC80 | c.1283G>C p.R428T | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV99779486; called by muse, mutect2, varscan2
- XPO6 | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 64/110 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as rs774960516, COSV100484740; called by muse, mutect2, varscan2
- ZFAT | c.2795G>A p.S932N | Missense Mutation (SNP) | VAF 125/312 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.079); catalogued as COSV100914852; called by muse, mutect2, varscan2
- ZFHX4 | c.5322G>T p.L1774F | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV99269900; called by muse, mutect2, varscan2
- ZKSCAN8 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 40/455 reads (9%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.788); catalogued as rs777066140, COSV57636806; called by muse, mutect2
- ZNF114 | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59944191; called by muse, mutect2, varscan2
- ZNF367 | c.790C>G p.Q264E | Missense Mutation (SNP) | VAF 49/71 reads (69%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV100930878; called by muse, mutect2, varscan2
- ZNF532 | c.3776G>A p.G1259D | Missense Mutation (SNP) | VAF 109/281 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.122); catalogued as rs1486486746; called by muse, mutect2, varscan2
- ZNF536 | c.1630C>A p.L544M | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV62834710; called by muse, mutect2, varscan2
- ZNF564 | c.650G>T p.R217I | Missense Mutation (SNP) | VAF 33/229 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.839); catalogued as COSV59434166; called by muse, mutect2, varscan2
- ZNF646 | c.805G>T p.A269S | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT tolerated (0.21); PolyPhen benign (0.1); catalogued as COSV56212427; called by muse, mutect2, varscan2
- ZNF69 | c.1466G>T p.C489F | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT tolerated (0.78); PolyPhen benign (0.163); catalogued as rs750082012; called by muse, mutect2, varscan2
- ZNF781 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs772286028, COSV62201701; called by muse, mutect2, varscan2
- ZNF85 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs879001677; called by muse, mutect2, varscan2
- ZSCAN4 | c.445C>A p.P149T | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV99989692; called by muse, mutect2, varscan2
- ABCB1 | c.2730G>T p.L910F | Missense Mutation (SNP) | VAF 222/549 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCB11 | c.3554T>C p.M1185T | Missense Mutation (SNP) | VAF 64/243 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ABCC12 | c.2858T>C p.L953S | Missense Mutation (SNP) | VAF 58/208 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- ABCD1 | c.18G>T p.R6S | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- AC092143.1 | c.1423G>T p.D475Y | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ACSF3 | c.739G>C p.V247L | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- ADAM23 | c.553G>T p.G185W | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAMTS16 | c.5A>T p.K2M | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ADAMTSL1 | c.1955G>T p.R652L | Missense Mutation (SNP) | VAF 57/101 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- ADCY7 | c.548A>T p.N183I | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- ADGRG4 | c.1513C>A p.H505N | Missense Mutation (SNP) | VAF 65/232 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ALDOB | c.47T>A p.L16H | Missense Mutation (SNP) | VAF 54/280 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALK | c.1949C>G p.P650R | Missense Mutation (SNP) | VAF 127/398 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ALMS1 | c.7052G>T p.W2351L | Missense Mutation (SNP) | VAF 111/275 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD49 | c.350A>G p.Y117C | Missense Mutation (SNP) | VAF 36/224 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- APOB | c.5386A>T p.T1796S | Missense Mutation (SNP) | VAF 61/190 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ARX | c.1534G>T p.V512L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- ATP8A1 | c.3160G>T p.G1054C | Missense Mutation (SNP) | VAF 109/289 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- ATXN1L | c.100A>G p.T34A | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AZI2 | c.1124T>G p.L375R | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- BBX | c.906+1G>T p.X302_splice | Splice Site (SNP) | VAF 104/256 reads (41%) | called by muse, mutect2, varscan2
- BEND5 | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 10/65 reads (15%) | called by muse, mutect2, varscan2
- BRDT | c.1855C>G p.Q619E | Missense Mutation (SNP) | VAF 101/160 reads (63%) | SIFT tolerated (0.34); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- BRSK2 | c.1756C>A p.P586T | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- BTK | c.840-1G>T p.X280_splice | Splice Site (SNP) | VAF 50/342 reads (15%) | called by muse, mutect2, varscan2
- BTNL2 | c.770T>C p.V257A | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- BTNL3 | c.1354G>T p.E452* | Nonsense Mutation (SNP) | VAF 39/111 reads (35%) | called by muse, mutect2, varscan2
- C12orf40 | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 137/460 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CACNA1C | c.749G>T p.G250V | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA1F | c.4310T>A p.V1437E | Missense Mutation (SNP) | VAF 85/280 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACTIN | c.2152G>T p.D718Y | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CADPS2 | c.3074A>T p.D1025V | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CASK | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 87/220 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CBX2 | c.859G>T p.G287W | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CCDC149 | c.157T>A p.Y53N | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CCDC181 | c.79A>T p.I27F | Missense Mutation (SNP) | VAF 72/239 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD8A | c.616T>A p.C206S | Missense Mutation (SNP) | VAF 88/172 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CDH13 | c.1082C>G p.P361R | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFAP47 | c.7217G>T p.G2406V | Missense Mutation (SNP) | VAF 137/361 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CIP2A | c.1635-1G>C p.X545_splice | Splice Site (SNP) | VAF 22/70 reads (31%) | called by muse, mutect2
- CLCN1 | c.245C>G p.T82R | Missense Mutation (SNP) | VAF 52/364 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.051); called by muse, varscan2
- CLDN4 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- CLEC18B | c.524T>A p.I175K | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.079); called by muse, mutect2
- CLEC18C | c.398G>C p.R133P | Missense Mutation (SNP) | VAF 87/174 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- CLPSL1 | c.152A>T p.Q51L | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- COL12A1 | c.375del p.G126Efs*35 | Frame Shift Del (DEL) | VAF 135/432 reads (31%) | called by mutect2, pindel, varscan2
- COL1A2 | c.2074G>T p.D692Y | Missense Mutation (SNP) | VAF 174/461 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- COL4A5 | c.3559C>A p.P1187T | Missense Mutation (SNP) | VAF 148/477 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- COL6A3 | c.3898C>G p.Q1300E | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CP | c.230A>G p.D77G | Missense Mutation (SNP) | VAF 102/270 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- CPE | c.367C>A p.L123M | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DAGLA | c.1140del p.F382Sfs*13 | Frame Shift Del (DEL) | VAF 29/61 reads (48%) | called by mutect2, pindel, varscan2
- DCHS1 | c.8399C>A p.S2800* | Nonsense Mutation (SNP) | VAF 57/112 reads (51%) | called by muse, mutect2, varscan2
- DCP1A | c.1528A>G p.T510A | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DIAPH1 | c.3133G>C p.E1045Q | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DIPK1B | c.1015G>C p.D339H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DIPK2B | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DMD | c.4904G>T p.G1635V | Missense Mutation (SNP) | VAF 217/576 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- DMD | c.4903G>C p.G1635R | Missense Mutation (SNP) | VAF 216/574 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- DMD | c.2855G>T p.R952M | Missense Mutation (SNP) | VAF 185/509 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DNAH10 | c.1703G>T p.C568F (on ENST00000409039; = p.C507F on NM_207437.3) | Missense Mutation (SNP) | VAF 25/197 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DNAH11 | c.2467T>A p.L823M | Missense Mutation (SNP) | VAF 79/210 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH12 | c.8258A>T p.K2753I (on ENST00000351747; = p.K3621I on NM_001366028.2) | Missense Mutation (SNP) | VAF 107/141 reads (76%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- DNAH9 | c.1431G>C p.Q477H | Missense Mutation (SNP) | VAF 43/65 reads (66%) | SIFT tolerated (0.12); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- DNAH9 | c.12203G>T p.G4068V | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAJC13 | c.6070C>G p.L2024V | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- DOK4 | c.386C>G p.P129R | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- DPH1 | c.1168A>T p.T390S | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT deleterious (0.04); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- DPP10 | c.1316A>G p.Y439C | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPP6 | c.1561G>A p.G521S (on ENST00000377770 / NM_001364500.2; = p.G459S on NM_001936.5) | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- DSG2 | c.1487G>T p.C496F | Missense Mutation (SNP) | VAF 36/468 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DTNB | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DYNC1I1 | c.437A>G p.H146R | Missense Mutation (SNP) | VAF 84/218 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- DYRK1A | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 101/287 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, varscan2
- EEF1D | c.254C>A p.A85D | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- EFCAB13 | c.2255A>G p.N752S | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); called by muse, mutect2
- ENAH | c.400G>T p.G134C | Missense Mutation (SNP) | VAF 142/315 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ENPP2 | c.2444G>T p.W815L (on ENST00000075322 / NM_001040092.3; = p.W867L on NM_006209.5) | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- EPB41L2 | c.2495G>A p.G832D | Missense Mutation (SNP) | VAF 76/238 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- ESPL1 | c.6251G>C p.G2084A | Missense Mutation (SNP) | VAF 80/184 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ESYT2 | c.812+1G>T p.X271_splice (on ENST00000613624; = p.X195_splice on NM_020728.3) | Splice Site (SNP) | VAF 143/373 reads (38%) | called by muse, mutect2, varscan2
- EZHIP | c.310C>G p.R104G | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAAP100 | c.392G>T p.C131F | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- FAT2 | c.10506+2T>C p.X3502_splice | Splice Site (SNP) | VAF 15/74 reads (20%) | called by muse, mutect2, varscan2
- FAT2 | c.4105G>T p.G1369W | Missense Mutation (SNP) | VAF 71/108 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FDFT1 | c.773G>A p.C258Y | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLG2 | c.4327C>A p.Q1443K | Missense Mutation (SNP) | VAF 110/381 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLNA | c.7402G>T p.G2468C (on ENST00000369850 / NM_001110556.2; = p.G2460C on NM_001456.3) | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLT1 | c.916A>C p.K306Q | Missense Mutation (SNP) | VAF 178/414 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- FOLR3 | c.214C>A p.Q72K | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- FOXD4L6 | c.1004G>T p.G335V | Missense Mutation (SNP) | VAF 60/82 reads (73%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by mutect2, varscan2
- FOXP2 | c.1507G>C p.V503L | Missense Mutation (SNP) | VAF 216/613 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- FOXP3 | c.89C>A p.P30H | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- FREM3 | c.3863A>T p.K1288M | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- GABBR1 | c.1425G>T p.W475C | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- GGH | c.407G>C p.G136A | Missense Mutation (SNP) | VAF 40/301 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- GIPC1 | c.970G>T p.A324S | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- GK2 | c.962C>A p.S321Y | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GMPPA | c.1161G>T p.L387= | Splice Region (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2
- GNB1 | c.159del p.H54Tfs*48 | Frame Shift Del (DEL) | VAF 31/83 reads (37%) | called by mutect2, pindel, varscan2
- GORASP2 | c.270G>T p.W90C | Missense Mutation (SNP) | VAF 121/306 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPA33 | c.115G>C p.V39L | Missense Mutation (SNP) | VAF 87/147 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- GPRASP1 | c.2952C>A p.D984E | Missense Mutation (SNP) | VAF 14/215 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.046); called by muse, mutect2
- GRIK1 | c.1145dup p.N382Kfs*8 | Frame Shift Ins (INS) | VAF 36/153 reads (24%) | called by mutect2, pindel, varscan2
- GRIPAP1 | c.2428C>T p.H810Y | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by mutect2, varscan2
- GUCY1B1 | c.503A>T p.Q168L | Missense Mutation (SNP) | VAF 54/81 reads (67%) | SIFT deleterious (0.05); PolyPhen benign (0.117); called by muse, varscan2
- HAPLN4 | c.410A>G p.D137G | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HAS1 | c.217T>C p.F73L | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2
- HCFC1 | c.3376A>T p.S1126C | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- HFE | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- HLF | c.432G>C p.M144I | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- HOXD9 | c.237G>C p.W79C | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- HS6ST1 | c.561del p.V188Cfs*5 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | called by mutect2, pindel, varscan2
- HSFX2 | c.169C>G p.P57A | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.867); called by mutect2, varscan2
- IFIH1 | c.2559G>T p.M853I | Missense Mutation (SNP) | VAF 79/252 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ISL2 | c.156C>A p.C52* | Nonsense Mutation (SNP) | VAF 17/56 reads (30%) | called by muse, mutect2, varscan2
- ISL2 | c.157C>A p.L53I | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KALRN | c.8060T>C p.L2687P (on ENST00000360013 / NM_001024660.4; = p.L990P on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/237 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- KCNA7 | c.674T>A p.L225Q | Missense Mutation (SNP) | VAF 72/143 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- KCNH8 | c.2787T>G p.S929R | Missense Mutation (SNP) | VAF 119/173 reads (69%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- KIAA0895 | c.166T>A p.F56I | Missense Mutation (SNP) | VAF 124/304 reads (41%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KIF26A | c.4000G>T p.G1334W | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- KIR3DL1 | c.55del p.A19Pfs*27 | Frame Shift Del (DEL) | VAF 20/145 reads (14%) | called by mutect2, pindel, varscan2
- KMT2D | c.3870_3880del p.R1291Pfs*30 | Frame Shift Del (DEL) | VAF 3/25 reads (12%) | called by mutect2, pindel
- LAMA2 | c.4232G>T p.G1411V | Missense Mutation (SNP) | VAF 125/323 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- LAMB2 | c.2265del p.S757Afs*35 | Frame Shift Del (DEL) | VAF 69/126 reads (55%) | called by mutect2, pindel, varscan2
- LGI2 | c.1479T>A p.D493E | Missense Mutation (SNP) | VAF 78/166 reads (47%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- LHX5 | c.623A>G p.H208R | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- LHX8 | c.199G>T p.G67C | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- LMO4 | c.106C>T p.L36F | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- LPIN2 | c.715G>T p.A239S | Missense Mutation (SNP) | VAF 70/357 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- LRRIQ1 | c.4638-1G>C p.X1546_splice | Splice Site (SNP) | VAF 90/268 reads (34%) | called by muse, varscan2
- MACF1 | c.2742G>T p.M914I | Missense Mutation (SNP) | VAF 19/153 reads (12%) | called by muse, mutect2, varscan2
- MAF1 | c.509C>A p.P170Q | Missense Mutation (SNP) | VAF 85/220 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAGEE2 | c.846_857del p.E283_N286del | In Frame Del (DEL) | VAF 107/286 reads (37%) | called by mutect2, pindel, varscan2
- MAPK9 | c.934G>T p.V312L | Missense Mutation (SNP) | VAF 33/277 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- MED12 | c.1590G>T p.E530D | Missense Mutation (SNP) | VAF 165/367 reads (45%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- MED12 | c.3980C>T p.P1327L | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MED14 | c.4064C>A p.P1355H | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); called by muse, mutect2
- METTL27 | c.502del p.R168Gfs*76 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | called by mutect2, pindel
- MRGPRF | c.675G>T p.E225D | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- MTHFR | c.675C>G p.I225M | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- MUC19 | c.922A>G p.S308G | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- MYF5 | c.198C>A p.H66Q | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- MYLK | c.1333G>T p.V445L | Missense Mutation (SNP) | VAF 91/246 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- NCKAP1L | c.2680del p.L894Cfs*5 | Frame Shift Del (DEL) | VAF 62/181 reads (34%) | called by mutect2, pindel, varscan2
- NELL1 | c.392A>T p.H131L | Missense Mutation (SNP) | VAF 106/203 reads (52%) | SIFT tolerated (0.68); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NHS | c.3695C>A p.T1232K | Missense Mutation (SNP) | VAF 92/293 reads (31%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- NKD1 | c.259+1G>A p.X87_splice | Splice Site (SNP) | VAF 56/128 reads (44%) | called by muse, mutect2, varscan2
- NLRP6 | c.1986C>A p.C662* | Nonsense Mutation (SNP) | VAF 13/72 reads (18%) | called by muse, mutect2, varscan2
- NR2F1 | c.629C>G p.P210R | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.34); called by mutect2, varscan2
- NRCAM | c.1786G>T p.V596F (on ENST00000379028 / NM_001371124.1; = p.V590F on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.017); called by muse, varscan2
- OBSCN | c.17689A>T p.I5897F | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- OPCML | c.1015G>C p.A339P | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- OR10AG1 | c.662C>A p.S221* | Nonsense Mutation (SNP) | VAF 35/168 reads (21%) | called by muse, mutect2, varscan2
- OR2B2 | c.67C>G p.L23V | Missense Mutation (SNP) | VAF 65/160 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR2M4 | c.345G>T p.L115F | Missense Mutation (SNP) | VAF 72/226 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- OR4A47 | c.137C>G p.T46S | Missense Mutation (SNP) | VAF 87/219 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- OR4N2 | c.455del p.G152Vfs*47 | Frame Shift Del (DEL) | VAF 53/196 reads (27%) | called by mutect2, varscan2
- OR51B2 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 85/160 reads (53%) | SIFT tolerated (0.38); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- OR56A5 | c.25A>G p.T9A | Missense Mutation (SNP) | VAF 48/228 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR5B3 | c.101T>C p.I34T | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR6S1 | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- OR8J1 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- OR9K2 | c.436G>T p.D146Y (on ENST00000305377; = p.D124Y on NM_001005243.1) | Missense Mutation (SNP) | VAF 92/208 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1194G>T p.E398D (on ENST00000259318 / NM_001136562.3; = p.E629D on NM_007203.5) | Missense Mutation (SNP) | VAF 42/56 reads (75%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PASD1 | c.1300C>G p.Q434E | Missense Mutation (SNP) | VAF 103/270 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- PCDHGB5 | c.601G>T p.D201Y | Missense Mutation (SNP) | VAF 89/132 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDHB | c.445_447delinsTG p.G149Wfs*6 | Frame Shift Del (DEL) | VAF 40/71 reads (56%) | called by pindel, varscan2*
- PHF24 | c.683A>T p.H228L | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); called by muse, varscan2
- PIP4P1 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 13/293 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.375); called by muse, mutect2
- PJA1 | c.517C>A p.R173S | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLXNA3 | c.2887G>A p.G963S | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.05); called by muse, mutect2
- PNPLA3 | c.688G>T p.D230Y | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); called by muse, mutect2
- POTEH | c.196T>A p.C66S | Missense Mutation (SNP) | VAF 148/428 reads (35%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.021); called by muse, varscan2
- PPP1R3F | c.1038G>T p.M346I | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP2R1B | c.1169C>A p.P390H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PRICKLE3 | c.446T>C p.L149P | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRPF40A | c.631C>T p.L211F | Missense Mutation (SNP) | VAF 111/462 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- PRSS21 | c.8C>A p.A3E | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PTPRF | c.3138dup p.L1047Sfs*94 | Frame Shift Ins (INS) | VAF 16/28 reads (57%) | called by mutect2, pindel
- PTPRQ | c.3258T>G p.I1086M (on ENST00000616559; = p.I1044M on NM_001145026.2) | Missense Mutation (SNP) | VAF 79/220 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- QSOX1 | c.1555G>A p.V519M | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.123); called by muse, varscan2
- RAB39B | c.608A>T p.E203V | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RAD50 | c.3427A>C p.I1143L | Missense Mutation (SNP) | VAF 151/218 reads (69%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); called by muse, varscan2
- RAD54L | c.761A>T p.K254M | Missense Mutation (SNP) | VAF 22/321 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.486); called by muse, mutect2
- RASL12 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- RFWD3 | c.1480C>A p.P494T | Missense Mutation (SNP) | VAF 78/179 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- RFX4 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT tolerated, low confidence (0.37); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- RGS4 | c.394T>A p.C132S | Missense Mutation (SNP) | VAF 62/108 reads (57%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- RHEB | c.305A>T p.K102I | Missense Mutation (SNP) | VAF 85/251 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RHO | c.554G>A p.C185Y | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- RHOB | c.290A>T p.E97V | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- RIMS2 | c.4048C>T p.Q1350* | Nonsense Mutation (SNP) | VAF 30/91 reads (33%) | called by muse, mutect2, varscan2
- ROBO4 | c.1712G>A p.G571D | Missense Mutation (SNP) | VAF 79/125 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RP1 | c.3866A>G p.D1289G | Missense Mutation (SNP) | VAF 216/729 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RSPH6A | c.1901C>T p.A634V | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2
- RYR2 | c.862C>A p.H288N | Missense Mutation (SNP) | VAF 72/130 reads (55%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- RYR2 | c.13773C>A p.Y4591* | Nonsense Mutation (SNP) | VAF 24/42 reads (57%) | called by muse, varscan2
- S100PBP | c.932_933insT p.T312Dfs*29 | Frame Shift Ins (INS) | VAF 130/238 reads (55%) | called by mutect2, pindel, varscan2
- SAGE1 | c.1559C>A p.P520Q | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- SAGE1 | c.1733T>C p.V578A | Missense Mutation (SNP) | VAF 11/198 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2
- SALL4 | c.1064C>T p.T355I | Missense Mutation (SNP) | VAF 97/112 reads (87%) | SIFT tolerated (0.08); PolyPhen benign (0.046); called by muse, varscan2
- SAMD9L | c.1491C>A p.F497L | Missense Mutation (SNP) | VAF 141/379 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCAF4 | c.2967G>T p.Q989H | Missense Mutation (SNP) | VAF 108/390 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.233); called by muse, varscan2
- SEMA6C | c.577G>T p.D193Y | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SETD1A | c.1916A>G p.D639G | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2
- SETD2 | c.7496_7504del p.I2499_T2501del | In Frame Del (DEL) | VAF 85/150 reads (57%) | called by mutect2, pindel, varscan2
- SFXN1 | c.708G>T p.M236I | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- SHOC2 | c.1293C>G p.I431M | Missense Mutation (SNP) | VAF 116/191 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- SHROOM3 | c.83T>A p.L28Q | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SIM1 | c.586C>A p.L196M | Missense Mutation (SNP) | VAF 22/642 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.254); called by muse, mutect2
- SLC7A13 | c.314C>A p.S105* | Nonsense Mutation (SNP) | VAF 62/180 reads (34%) | called by muse, mutect2, varscan2
- SLC9A9 | c.1610T>G p.L537R | Missense Mutation (SNP) | VAF 37/447 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SLIT3 | c.4309G>T p.G1437C | Missense Mutation (SNP) | VAF 63/137 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLITRK4 | c.1486G>C p.A496P | Missense Mutation (SNP) | VAF 103/395 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- SMC6 | c.1208G>C p.R403P | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- SNTG1 | c.883C>A p.Q295K | Missense Mutation (SNP) | VAF 73/203 reads (36%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.824); called by muse, varscan2
- SPATA20 | c.2212dup p.D738Gfs*29 (on ENST00000356488 / NM_001258372.1; = p.D754Gfs*29 on NM_022827.4) | Frame Shift Ins (INS) | VAF 20/45 reads (44%) | called by mutect2, pindel, varscan2
- SPN | c.647G>A p.S216N | Missense Mutation (SNP) | VAF 53/93 reads (57%) | SIFT tolerated (0.38); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- STX18 | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SUPT20H | c.853A>G p.K285E (on ENST00000350612 / NM_001014286.3; = p.K286E on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/74 reads (61%) | SIFT tolerated (0.05); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- SWT1 | c.1205A>T p.K402I | Missense Mutation (SNP) | VAF 58/250 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- TAF1L | c.1813G>A p.G605R | Missense Mutation (SNP) | VAF 75/101 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TAF9B | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 75/209 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TAOK2 | c.2622del p.K875Rfs*21 | Frame Shift Del (DEL) | VAF 17/154 reads (11%) | called by mutect2, pindel, varscan2
- TAS1R1 | c.723C>G p.F241L | Missense Mutation (SNP) | VAF 88/137 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- TBC1D17 | c.1747-2A>T p.X583_splice | Splice Site (SNP) | VAF 66/111 reads (59%) | called by muse, mutect2, varscan2
- TBR1 | c.1531G>T p.A511S | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (1); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TECPR1 | c.3230A>T p.N1077I | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEX11 | c.1499T>A p.I500N (on ENST00000344304; = p.I485N on NM_031276.3) | Missense Mutation (SNP) | VAF 108/249 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- TEX13C | c.1549C>G p.P517A | Missense Mutation (SNP) | VAF 71/149 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- TEX55 | c.1472T>G p.I491R | Missense Mutation (SNP) | VAF 98/368 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- THNSL2 | c.35G>T p.R12L | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.3); PolyPhen benign (0.057); called by muse, mutect2
- TIPIN | c.184A>G p.R62G | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- TNIK | c.3169+1G>A p.X1057_splice | Splice Site (SNP) | VAF 37/88 reads (42%) | called by muse, mutect2, varscan2
- TNIP2 | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- TNN | c.685A>G p.S229G | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- TOP3A | c.44G>T p.R15L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.048); called by muse, mutect2
- TRIP10 | c.371A>T p.Q124L | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- TRIP12 | c.721A>T p.S241C | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TTN | c.94588T>A p.Y31530N (on ENST00000591111; = p.Y24106N on NM_003319.4) | Missense Mutation (SNP) | VAF 118/255 reads (46%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.84403G>T p.G28135* (on ENST00000591111; = p.G20711* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 30/186 reads (16%) | called by muse, varscan2
- USP27X | c.787C>A p.L263I | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- USP6 | c.2405T>C p.I802T | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- VCAM1 | c.787G>T p.D263Y | Missense Mutation (SNP) | VAF 48/294 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- VHLL | c.152G>T p.R51L | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- VPS50 | c.2722A>G p.K908E | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- WDR11 | c.1519C>A p.L507I | Missense Mutation (SNP) | VAF 31/235 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- WDR45 | c.32G>T p.S11I | Missense Mutation (SNP) | VAF 60/248 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- WDR62 | c.385G>T p.G129W | Missense Mutation (SNP) | VAF 57/191 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDR87 | c.1306G>T p.G436* | Nonsense Mutation (SNP) | VAF 24/100 reads (24%) | called by muse, mutect2, varscan2
- ZBTB7B | c.434G>T p.G145V (on ENST00000292176; = p.G179V on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFP28 | c.1209A>T p.K403N | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.057); called by muse, varscan2
- ZNF143 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ZNF292 | c.6575A>G p.H2192R | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- ZNF439 | c.1235G>T p.C412F | Missense Mutation (SNP) | VAF 91/176 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF549 | c.1088_1089del p.C363Yfs*12 (on ENST00000376233 / NM_001199295.2; = p.C350Yfs*12 on NM_153263.2) | Frame Shift Del (DEL) | VAF 64/170 reads (38%) | called by pindel, varscan2
- ZNF568 | c.490G>T p.D164Y | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2
- ZNF626 | c.62T>A p.L21Q | Missense Mutation (SNP) | VAF 62/306 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ZNF630 | c.1427G>T p.G476V | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ZNF724 | c.1115G>T p.G372V | Missense Mutation (SNP) | VAF 74/152 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ZNF729 | c.1277A>T p.H426L | Missense Mutation (SNP) | VAF 42/426 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF775 | c.977G>T p.R326L | Missense Mutation (SNP) | VAF 67/153 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZSCAN9 | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- ABCA13 | c.13401C>T p.S4467= | Silent (SNP) | VAF 51/144 reads (35%) | catalogued as rs757057171; called by muse, mutect2, varscan2
- ABCA6 | c.2940T>C p.I980= | Silent (SNP) | VAF 96/221 reads (43%) | catalogued as rs750063702, COSV52638392; called by muse, mutect2, varscan2
- AC006059.2 | c.2001C>G p.S667= | Silent (SNP) | VAF 70/84 reads (83%) | called by muse, mutect2, varscan2
- ADGRF5 | c.2058A>G p.L686= | Silent (SNP) | VAF 142/330 reads (43%) | called by muse, mutect2, varscan2
- AKAP4 | c.2103A>C p.V701= | Silent (SNP) | VAF 102/285 reads (36%) | called by muse, mutect2, varscan2
- AMOTL1 | c.2034G>T p.L678= | Silent (SNP) | VAF 12/114 reads (11%) | called by muse, mutect2, varscan2
- APOBEC3F | c.552A>G p.L184= | Silent (SNP) | VAF 59/105 reads (56%) | catalogued as rs149410972; called by muse, mutect2, varscan2
- ATP2A2 | c.1497A>G p.T499= | Silent (SNP) | VAF 164/483 reads (34%) | called by muse, mutect2, varscan2
- CCDC175 | c.978A>G p.E326= | Silent (SNP) | VAF 58/147 reads (39%) | called by muse, varscan2
- CDH8 | c.426G>A p.E142= | Silent (SNP) | VAF 72/384 reads (19%) | called by muse, mutect2, varscan2
- CDH9 | c.657T>C p.T219= | Silent (SNP) | VAF 64/183 reads (35%) | catalogued as rs771433767, COSV99142424; called by muse, mutect2, varscan2
- CNGA2 | c.1194C>T p.F398= | Silent (SNP) | VAF 79/295 reads (27%) | catalogued as rs1351027080, COSV61703840; called by muse, mutect2, varscan2
- COL6A6 | c.3636C>A p.T1212= | Silent (SNP) | VAF 52/147 reads (35%) | called by muse, mutect2, varscan2
- CX3CL1 | c.987T>A p.T329= | Silent (SNP) | VAF 5/9 reads (56%) | called by muse, mutect2
- CYP11B2 | c.228G>T p.G76= | Silent (SNP) | VAF 58/178 reads (33%) | called by muse, mutect2, varscan2
- DCAF11 | c.354G>A p.G118= | Silent (SNP) | VAF 79/199 reads (40%) | called by muse, mutect2, varscan2
- DCDC2C | c.807A>G p.E269= | Silent (SNP) | VAF 17/116 reads (15%) | called by muse, mutect2
- DIP2A | c.3735C>T p.F1245= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV100595779; called by muse, mutect2, varscan2
- DMTF1 | c.981C>T p.N327= | Silent (SNP) | VAF 140/401 reads (35%) | called by muse, mutect2, varscan2
- DNAH5 | c.10653A>G p.K3551= | Silent (SNP) | VAF 41/297 reads (14%) | called by muse, mutect2, varscan2
- DRP2 | c.2130G>C p.P710= | Silent (SNP) | VAF 52/121 reads (43%) | catalogued as COSV65810285; called by muse, mutect2, varscan2
- DUSP11 | c.33A>G p.V11= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as rs765095433; called by muse, mutect2, varscan2
- EGFL6 | c.1590C>G p.G530= | Silent (SNP) | VAF 22/237 reads (9%) | called by muse, mutect2
- EPB42 | c.1434C>A p.L478= (on ENST00000441366 / NM_001114134.2; = p.L508= on NM_000119.3) | Silent (SNP) | VAF 41/108 reads (38%) | called by muse, mutect2, varscan2
- EVC | c.1389G>T p.T463= | Silent (SNP) | VAF 50/198 reads (25%) | catalogued as COSV53829283, COSV53834148; called by mutect2, varscan2
- EXOC6 | c.1236A>T p.R412= | Silent (SNP) | VAF 119/174 reads (68%) | called by muse, mutect2, varscan2
- EXPH5 | c.5214C>A p.T1738= | Silent (SNP) | VAF 21/146 reads (14%) | called by muse, mutect2, varscan2
- FAM111B | c.1173T>C p.Y391= | Silent (SNP) | VAF 87/154 reads (56%) | catalogued as rs1412384177; called by muse, mutect2, varscan2
- FH | c.42C>G p.L14= | Silent (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- FMO4 | c.1482G>A p.L494= | Silent (SNP) | VAF 38/290 reads (13%) | catalogued as COSV63000854; called by muse, mutect2, varscan2
- GATA6 | c.42C>T p.F14= | Silent (SNP) | VAF 18/49 reads (37%) | called by muse, mutect2, varscan2
- GCGR | c.669C>G p.G223= | Silent (SNP) | VAF 7/76 reads (9%) | called by muse, mutect2
- GMPS | c.1341A>C p.V447= | Silent (SNP) | VAF 150/412 reads (36%) | called by muse, mutect2, varscan2
- GPLD1 | c.1386C>T p.D462= | Silent (SNP) | VAF 44/111 reads (40%) | catalogued as rs1062506, COSV100015424; called by muse, mutect2, varscan2
- GUCY2C | c.1806A>T p.S602= | Silent (SNP) | VAF 57/162 reads (35%) | called by muse, mutect2, varscan2
- HRNR | c.8514T>C p.Y2838= | Silent (SNP) | VAF 17/132 reads (13%) | catalogued as COSV64258045; called by muse, mutect2, varscan2
- IDS | c.396G>T p.S132= | Silent (SNP) | VAF 45/208 reads (22%) | catalogued as COSV100557903; called by muse, mutect2, varscan2
- IGHE | c.135A>T p.T45= | Silent (SNP) | VAF 82/159 reads (52%) | called by muse, mutect2, varscan2
- ITM2C | c.111G>T p.T37= | Silent (SNP) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- ITSN2 | c.5034C>T p.P1678= | Silent (SNP) | VAF 34/135 reads (25%) | catalogued as rs149080724; called by muse, mutect2, varscan2
- KCNJ1 | c.246C>T p.T82= | Silent (SNP) | VAF 81/141 reads (57%) | called by muse, mutect2, varscan2
- KCNU1 | c.1935C>T p.S645= | Silent (SNP) | VAF 65/200 reads (33%) | catalogued as rs752687362; called by muse, mutect2, varscan2
- KIR2DL4 | c.258G>T p.V86= (on ENST00000396284; = p.V47= on NM_001080770.2) | Silent (SNP) | VAF 32/159 reads (20%) | called by muse, mutect2, varscan2
- KRT79 | c.42G>A p.G14= | Silent (SNP) | VAF 64/208 reads (31%) | called by muse, mutect2, varscan2
- KRTAP10-7 | c.723C>T p.P241= | Silent (SNP) | VAF 47/151 reads (31%) | catalogued as rs587638590; called by muse, mutect2, varscan2
- LRPAP1 | c.57G>T p.L19= | Silent (SNP) | VAF 36/75 reads (48%) | called by muse, mutect2, varscan2
- MAD1L1 | c.1839G>C p.L613= | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as COSV56235998; called by muse, mutect2
- MAGEB3 | c.498T>A p.V166= | Silent (SNP) | VAF 98/302 reads (32%) | called by muse, mutect2, varscan2
- MCOLN1 | c.1482C>T p.S494= | Silent (SNP) | VAF 43/260 reads (17%) | called by muse, mutect2, varscan2
- MEGF10 | c.204A>G p.K68= | Silent (SNP) | VAF 25/139 reads (18%) | called by muse, mutect2, varscan2
- MYCBP2 | c.13155C>T p.D4385= (on ENST00000357337; = p.D4423= on NM_015057.5) | Silent (SNP) | VAF 18/131 reads (14%) | catalogued as rs756368403; called by muse, mutect2, varscan2
- MYH6 | c.2985C>A p.T995= | Silent (SNP) | VAF 69/207 reads (33%) | catalogued as rs1392879222; called by muse, mutect2, varscan2
- MYH8 | c.4788C>A p.V1596= | Silent (SNP) | VAF 185/255 reads (73%) | catalogued as COSV67970973; called by muse, mutect2, varscan2
- NCDN | c.1812A>T p.S604= | Silent (SNP) | VAF 28/41 reads (68%) | called by muse, mutect2, varscan2
- NFS1 | c.909G>T p.G303= | Silent (SNP) | VAF 91/243 reads (37%) | catalogued as rs1332409380, COSV65053792; called by muse, mutect2, varscan2
- NID2 | c.1614C>A p.G538= | Silent (SNP) | VAF 33/67 reads (49%) | catalogued as COSV99356282; called by muse, mutect2, varscan2
- NLRP11 | c.807A>T p.P269= | Silent (SNP) | VAF 91/158 reads (58%) | called by muse, mutect2, varscan2
- NPY1R | c.921C>A p.L307= | Silent (SNP) | VAF 27/124 reads (22%) | called by muse, mutect2, varscan2
- NR3C2 | c.336A>T p.V112= | Silent (SNP) | VAF 33/274 reads (12%) | called by muse, mutect2, varscan2
- NXPH1 | c.234C>A p.T78= | Silent (SNP) | VAF 70/181 reads (39%) | catalogued as rs778080583; called by muse, mutect2, varscan2
- OR11H12 | c.30C>A p.G10= | Silent (SNP) | VAF 93/413 reads (23%) | catalogued as COSV101612494; called by muse, mutect2, varscan2
- OR51Q1 | c.30A>G p.E10= | Silent (SNP) | VAF 26/48 reads (54%) | called by mutect2, varscan2
- OR52I2 | c.501G>C p.T167= | Silent (SNP) | VAF 52/273 reads (19%) | called by muse, mutect2, varscan2
- OR6B3 | c.837A>G p.T279= | Silent (SNP) | VAF 67/219 reads (31%) | called by muse, mutect2, varscan2
- OTOP2 | c.309C>T p.L103= | Silent (SNP) | VAF 14/18 reads (78%) | catalogued as rs1439956024; called by muse, mutect2
- PCDH11X | c.2202A>G p.T734= | Silent (SNP) | VAF 97/264 reads (37%) | catalogued as rs1166653890; called by muse, mutect2, varscan2
- PCDHA1 | c.1578G>A p.E526= | Silent (SNP) | VAF 157/211 reads (74%) | called by muse, mutect2, varscan2
- PCDHB1 | c.1242G>A p.E414= | Silent (SNP) | VAF 85/139 reads (61%) | catalogued as rs782270613; called by muse, mutect2, varscan2
- PEPD | c.72C>T p.A24= | Silent (SNP) | VAF 70/143 reads (49%) | called by muse, mutect2, varscan2
- PIKFYVE | c.4581T>C p.P1527= | Silent (SNP) | VAF 32/375 reads (9%) | called by muse, mutect2
- PKN1 | c.1587A>C p.T529= | Silent (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- POLA2 | c.15C>T p.A5= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as rs896276038; called by muse, mutect2, varscan2
- PTPRZ1 | c.2859T>C p.S953= | Silent (SNP) | VAF 128/314 reads (41%) | called by muse, varscan2
- RAB3GAP2 | c.2668C>T p.L890= | Silent (SNP) | VAF 119/271 reads (44%) | called by muse, mutect2, varscan2
- RGS22 | c.1875T>G p.T625= | Silent (SNP) | VAF 55/414 reads (13%) | called by muse, mutect2, varscan2
- SCN5A | c.5244C>T p.G1748= (on ENST00000333535 / NM_198056.3; = p.G1747= on NM_000335.5) | Silent (SNP) | VAF 134/168 reads (80%) | called by muse, mutect2, varscan2
- SCN9A | c.2055C>A p.L685= (on ENST00000303354; = p.L674= on NM_002977.3) | Silent (SNP) | VAF 73/321 reads (23%) | catalogued as COSV100313101; called by muse, mutect2, varscan2
- SEMA6C | c.576G>T p.A192= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100501667; called by muse, mutect2, varscan2
- SERPINB6 | c.279T>C p.S93= (on ENST00000612421 / NM_001271823.2; = p.S74= on NM_004568.6) | Silent (SNP) | VAF 12/186 reads (6%) | called by muse, mutect2
- SIM2 | c.423G>T p.T141= | Silent (SNP) | VAF 52/135 reads (39%) | catalogued as rs138136486; called by muse, mutect2, varscan2
- SLC10A3 | c.177A>T p.P59= | Silent (SNP) | VAF 26/78 reads (33%) | called by muse, mutect2, varscan2
- SLC35D3 | c.774G>A p.V258= | Silent (SNP) | VAF 14/112 reads (13%) | called by muse, mutect2, varscan2
- SLC9A3 | c.1411C>A p.R471= | Silent (SNP) | VAF 83/182 reads (46%) | called by muse, mutect2, varscan2
- STAG1 | c.3306T>C p.T1102= | Silent (SNP) | VAF 23/51 reads (45%) | called by muse, mutect2, varscan2
- STK10 | c.426A>G p.L142= | Silent (SNP) | VAF 42/122 reads (34%) | called by muse, mutect2, varscan2
- SUPT20HL2 | c.702G>T p.P234= | Silent (SNP) | VAF 61/164 reads (37%) | called by muse, mutect2, varscan2
- SYNE2 | c.18825A>G p.S6275= | Silent (SNP) | VAF 215/453 reads (47%) | called by muse, mutect2, varscan2
- TEX55 | c.1470T>C p.S490= | Silent (SNP) | VAF 95/357 reads (27%) | called by muse, mutect2
- TRIM51GP | c.321C>T p.D107= | Silent (SNP) | VAF 28/170 reads (16%) | catalogued as rs745582380; called by muse, mutect2, varscan2
- TRPV3 | c.1143G>A p.A381= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as rs141437962; called by muse, mutect2, varscan2
- TTN | c.44742T>A p.P14914= (on ENST00000591111; = p.P7490= on NM_003319.4) | Silent (SNP) | VAF 92/284 reads (32%) | called by muse, mutect2, varscan2
- TTN | c.20553C>G p.V6851= (on ENST00000591111; = p.V5924= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/136 reads (27%) | called by muse, mutect2, varscan2
- UBR4 | c.13143G>A p.P4381= | Silent (SNP) | VAF 36/238 reads (15%) | catalogued as rs111323489; called by muse, mutect2, varscan2
- UGT1A10 | c.63C>T p.G21= | Silent (SNP) | VAF 51/92 reads (55%) | catalogued as rs776178940; called by muse, mutect2, varscan2
- UNC13C | c.5508T>C p.S1836= | Silent (SNP) | VAF 28/224 reads (13%) | catalogued as COSV52868128; called by muse, mutect2, varscan2
- UPRT | c.78C>T p.P26= | Silent (SNP) | VAF 37/86 reads (43%) | called by muse, varscan2
- UPRT | c.231G>A p.E77= | Silent (SNP) | VAF 38/104 reads (37%) | called by muse, varscan2
- VBP1 | c.579C>G p.T193= | Silent (SNP) | VAF 83/324 reads (26%) | catalogued as COSV99660763; called by muse, mutect2, varscan2
- WSCD2 | c.1644A>T p.A548= | Silent (SNP) | VAF 24/59 reads (41%) | called by muse, mutect2, varscan2
- ZNF221 | c.1101A>G p.K367= | Silent (SNP) | VAF 25/167 reads (15%) | called by muse, mutect2, varscan2
- ZNF521 | c.3238C>T p.L1080= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as COSV64122948, COSV64127674; called by muse, mutect2, varscan2
- ZNF658 | c.267G>T p.G89= | Silent (SNP) | VAF 116/161 reads (72%) | called by muse, mutect2, varscan2
- AC068643.2 | n.593+3663A>T | Intron (SNP) | VAF 68/222 reads (31%) | called by muse, mutect2, varscan2
- AC104078.1 | n.227C>G | RNA (SNP) | VAF 67/245 reads (27%) | called by muse, mutect2, varscan2
- AC107023.1 | n.26-6288C>T | Intron (SNP) | VAF 122/288 reads (42%) | catalogued as rs764606429; called by muse, mutect2, varscan2
- AC107023.1 | chr12:40444135 C>A | 5'Flank (SNP) | VAF 133/340 reads (39%) | called by muse, mutect2, varscan2
- AC139495.2 | n.733G>T | RNA (SNP) | VAF 17/506 reads (3%) | catalogued as rs1361626354; called by muse, mutect2
- ALG2 | c.*364T>G | 3'UTR (SNP) | VAF 38/281 reads (14%) | called by muse, mutect2, varscan2
- ANKRD26P1 | n.1993A>G | RNA (SNP) | VAF 123/266 reads (46%) | called by muse, mutect2, varscan2
- AP4M1 | c.-49G>A | 5'UTR (SNP) | VAF 34/65 reads (52%) | called by muse, mutect2, varscan2
- AVPR2 | chrX:153905055 A>G | 5'Flank (SNP) | VAF 38/100 reads (38%) | called by muse, mutect2, varscan2
- BLM | c.1088-148A>T | Intron (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2, varscan2
- CACNA1G | c.-86G>T | 5'UTR (SNP) | VAF 10/18 reads (56%) | called by muse, mutect2
- CARD8 | c.-20A>G | 5'UTR (SNP) | VAF 24/108 reads (22%) | catalogued as rs1035416358; called by muse, mutect2, varscan2
- CLASP1 | c.196-646_196-645insCTA | Intron (INS) | VAF 47/119 reads (39%) | called by mutect2, pindel, varscan2
- CLCN7 | c.1884-34G>T | Intron (SNP) | VAF 38/80 reads (48%) | called by muse, mutect2, varscan2
- CMC2 | c.81+5363G>C | Intron (SNP) | VAF 34/219 reads (16%) | catalogued as rs549407801; called by muse, mutect2, varscan2
- CSTF2 | c.58+122G>T | Intron (SNP) | VAF 70/192 reads (36%) | catalogued as COSV63376406; called by muse, mutect2, varscan2
- CTNNB1 | c.1684-44A>G | Intron (SNP) | VAF 145/202 reads (72%) | called by muse, mutect2, varscan2
- DCDC1 | c.2715+8767T>C | Intron (SNP) | VAF 20/153 reads (13%) | called by muse, mutect2, varscan2
- DCHS2 | n.8062C>T | RNA (SNP) | VAF 42/86 reads (49%) | called by muse, mutect2, varscan2
- DHFR | c.-117dup | 5'UTR (INS) | VAF 8/12 reads (67%) | catalogued as rs754309248; called by mutect2, varscan2
- DHRS7 | c.972+124T>C | Intron (SNP) | VAF 12/34 reads (35%) | catalogued as rs748297796; called by muse, mutect2, varscan2
- DNAJC5 | c.-11-8886T>C | Intron (SNP) | VAF 28/158 reads (18%) | catalogued as rs1177853346; called by muse, varscan2
- EPHB6 | c.1865+37A>G | Intron (SNP) | VAF 38/100 reads (38%) | called by muse, mutect2, varscan2
- ERLIN2 | chr8:37736451 C>A | 5'Flank (SNP) | VAF 12/16 reads (75%) | called by muse, mutect2
- FAM149A | c.1602+297A>G | Intron (SNP) | VAF 13/82 reads (16%) | called by muse, mutect2, varscan2
- FHL1 | c.*669C>A | 3'UTR (SNP) | VAF 71/240 reads (30%) | called by muse, mutect2, varscan2
- FLJ40194 | n.269C>G | RNA (SNP) | VAF 33/108 reads (31%) | called by muse, mutect2, varscan2
- GABRE | c.784+1218A>T | Intron (SNP) | VAF 62/173 reads (36%) | called by muse, mutect2, varscan2
- GNGT1 | c.-11-37C>A | Intron (SNP) | VAF 108/309 reads (35%) | catalogued as rs1320551612; called by muse, mutect2, varscan2
- HES4 | c.205-32G>T | Intron (SNP) | VAF 6/48 reads (13%) | catalogued as rs757783143; called by mutect2, varscan2
- HSP90AA4P | n.1885G>T | RNA (SNP) | VAF 63/118 reads (53%) | called by muse, mutect2, varscan2
- HYDIN | c.2075+398T>C | Intron (SNP) | VAF 69/301 reads (23%) | catalogued as rs1237144840; called by muse, mutect2, varscan2
- IVNS1ABP | c.657+498C>T | Intron (SNP) | VAF 55/236 reads (23%) | catalogued as rs1013790583, COSV62250104; called by muse, mutect2, varscan2
- LGALS4 | c.570+24G>T | Intron (SNP) | VAF 26/75 reads (35%) | called by muse, mutect2, varscan2
- LHX4 | c.248+19T>C | Intron (SNP) | VAF 39/168 reads (23%) | called by muse, mutect2, varscan2
- MDS2 | n.459G>C | RNA (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- MRRFP1 | n.568C>A | RNA (SNP) | VAF 76/209 reads (36%) | called by muse, mutect2, varscan2
- MTMR1 | c.1656+188C>T | Intron (SNP) | VAF 9/29 reads (31%) | catalogued as rs1557417584; called by muse, mutect2, varscan2
- NCAM1 | c.2456+1154G>A | Intron (SNP) | VAF 17/151 reads (11%) | called by muse, mutect2, varscan2
- NCOA4 | c.-15+3043G>A | Intron (SNP) | VAF 116/178 reads (65%) | called by muse, mutect2, varscan2
- OBSCN | c.11660-1848G>A | Intron (SNP) | VAF 28/120 reads (23%) | catalogued as rs758570719, COSV52763535; called by muse, mutect2, varscan2
- ONECUT2 | c.1229-9242G>C | Intron (SNP) | VAF 57/138 reads (41%) | called by muse, mutect2, varscan2
- PBDC1 | c.-18G>C | 5'UTR (SNP) | VAF 33/103 reads (32%) | called by muse, mutect2, varscan2
- PDPK1 | c.1344-2947C>T | Intron (SNP) | VAF 82/153 reads (54%) | catalogued as rs1204200931; called by muse, mutect2, varscan2
- PIK3R6 | c.-179C>A | 5'UTR (SNP) | VAF 21/31 reads (68%) | catalogued as rs762918541; called by muse, mutect2, varscan2
- PLA2G6 | c.1348+851G>C | Intron (SNP) | VAF 17/77 reads (22%) | catalogued as COSV59269519; called by muse, mutect2, varscan2
- PLCG2 | c.*44G>A | 3'UTR (SNP) | VAF 102/217 reads (47%) | called by muse, mutect2, varscan2
- PRMT2 | c.490-48G>T | Intron (SNP) | VAF 19/116 reads (16%) | called by muse, mutect2, varscan2
- RARB | c.179-32347G>T | Intron (SNP) | VAF 14/67 reads (21%) | called by muse, mutect2, varscan2
- RPGR | c.2520+88G>T | Intron (SNP) | VAF 99/336 reads (29%) | catalogued as COSV58840546; called by muse, mutect2, varscan2
- SCN1A | c.265-36A>G | Intron (SNP) | VAF 68/196 reads (35%) | called by muse, mutect2, varscan2
- SETD9 | c.-12C>A | 5'UTR (SNP) | VAF 31/44 reads (70%) | called by muse, mutect2, varscan2
- SGCD | c.-1+2319G>A | Intron (SNP) | VAF 57/94 reads (61%) | catalogued as rs752924735; called by muse, mutect2, varscan2
- SIRT2 | c.226+1539A>T | Intron (SNP) | VAF 51/106 reads (48%) | called by muse, mutect2, varscan2
- SLC12A8 | c.737-80_737-63del | Intron (DEL) | VAF 10/90 reads (11%) | called by mutect2, pindel
- SP110 | c.1591-27C>T | Intron (SNP) | VAF 33/134 reads (25%) | catalogued as rs764475133; called by muse, mutect2, varscan2
- STAT3 | c.1234-28G>A | Intron (SNP) | VAF 117/277 reads (42%) | called by muse, mutect2, varscan2
- TF | c.1687+9A>G | Intron (SNP) | VAF 88/225 reads (39%) | called by muse, mutect2, varscan2
- TPRX2P | n.364G>T | RNA (SNP) | VAF 6/58 reads (10%) | called by muse, varscan2
- TRIM53AP | n.405A>T | RNA (SNP) | VAF 15/78 reads (19%) | called by mutect2, varscan2
- TYR | c.-8G>C | 5'UTR (SNP) | VAF 43/209 reads (21%) | called by muse, mutect2, varscan2
- UGT2B27P | n.876T>C | RNA (SNP) | VAF 176/415 reads (42%) | called by muse, varscan2
- USP34 | chr2:61183586 G>A | 3'Flank (SNP) | VAF 44/134 reads (33%) | catalogued as rs886236533; called by muse, mutect2, varscan2
- WDR37 | c.*2G>T | 3'UTR (SNP) | VAF 49/67 reads (73%) | called by muse, mutect2, varscan2
- ZNF252P | n.245+4690G>T | Intron (SNP) | VAF 18/65 reads (28%) | called by muse, mutect2, varscan2
- ZNF276 | c.510-18C>G | Intron (SNP) | VAF 38/75 reads (51%) | called by muse, mutect2, varscan2
